Somatic mutation profile of cancer-model specimen HCM-BROD-0040-C74-85B (Adherent Cell Line, passage 7; aliquot HCM-BROD-0040-C74-85B-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-BROD-0040-C74, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.8 years (1,030 days).
Specimen HCM-BROD-0040-C74-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aa8aa0c-481f-4f51-8a7a-e717eca88e22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0040-C74-11A (Solid Tissue Normal), aliquot HCM-BROD-0040-C74-11A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb2c16c1-97a6-4774-b8e0-228eef6b477c

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.3055G>A p.G1019R | Missense Mutation (SNP) | VAF 236/760 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs190551509; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CACNG2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 29/859 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1430487866; called by muse, mutect2
- CCT8L2 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 205/687 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764133439; called by muse, mutect2, varscan2
- HTR1D | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 192/596 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs757946711, COSV58447419; called by muse, mutect2, varscan2
- PRRT4 | c.1312G>C p.D438H | Missense Mutation (SNP) | VAF 207/827 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV71054362; called by muse, mutect2, varscan2
- PRSS54 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 18/644 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as rs1385906259; called by muse, mutect2
- CACHD1 | c.3290G>T p.G1097V | Missense Mutation (SNP) | VAF 53/523 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRAMP1 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 87/825 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GIPC3 | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 233/769 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 164/512 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.019); called by muse, varscan2
- KIAA0100 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 197/657 reads (30%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LAMA1 | c.5069C>A p.S1690Y | Missense Mutation (SNP) | VAF 21/496 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- MAGEB17 | c.819G>A p.W273* | Nonsense Mutation (SNP) | VAF 204/330 reads (62%) | called by muse, mutect2, varscan2
- MALRD1 | c.3013G>A p.G1005R | Missense Mutation (SNP) | VAF 81/329 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MINPP1 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 222/745 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MYOF | c.3916A>G p.I1306V | Missense Mutation (SNP) | VAF 88/306 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR6C65 | c.614T>A p.L205H | Missense Mutation (SNP) | VAF 52/574 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PWWP2B | c.1498G>C p.G500R | Missense Mutation (SNP) | VAF 25/753 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RNF215 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 39/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF862 | c.2864G>A p.W955* | Nonsense Mutation (SNP) | VAF 59/491 reads (12%) | called by muse, mutect2, varscan2
- H1-0 | c.222C>A p.R74= | Silent (SNP) | VAF 121/464 reads (26%) | called by muse, mutect2, varscan2
- OR8S1 | c.109C>T p.L37= | Silent (SNP) | VAF 158/624 reads (25%) | called by muse, mutect2
- PKP4 | c.2985G>A p.R995= | Silent (SNP) | VAF 98/357 reads (27%) | called by muse, mutect2, varscan2
- TMEM63C | c.2160G>A p.E720= | Silent (SNP) | VAF 108/393 reads (27%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.12T>C p.F4= | Silent (SNP) | VAF 14/438 reads (3%) | catalogued as rs1405432285; called by muse, mutect2
- ZP4 | c.951G>T p.L317= | Silent (SNP) | VAF 24/438 reads (5%) | called by muse, mutect2
- DNAJC17 | c.*304G>A | 3'UTR (SNP) | VAF 284/894 reads (32%) | catalogued as rs1401080965; called by muse, mutect2
